Somatic mutation profile of tumor specimen TCGA-2Z-A9JK-01A (aliquot TCGA-2Z-A9JK-01A-11D-A42J-10) from TCGA case TCGA-2Z-A9JK, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 50.8 years (18,540 days).
Specimen TCGA-2Z-A9JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2398cf24-c346-4c78-97d3-ea342bf016af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JK-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JK-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7faf346-91a5-4797-9c6e-9f26c7ff86a7

The open-access MAF lists 88 somatic variants for this specimen: 72 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 59, Silent 16, Frame Shift Del 10, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF5 | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as COSV51936715; called by muse, mutect2, varscan2
- ALG9 | c.1463A>T p.Q488L (on ENST00000614444 / NM_001352418.1; = p.Q495L on NM_024740.2) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV101211968; called by muse, mutect2, varscan2
- ANKRD11 | c.7666A>G p.T2556A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99971006; called by muse, mutect2, varscan2
- BCORL1 | c.4895T>G p.L1632R | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99501311; called by muse, mutect2, varscan2
- C4orf3 | c.80A>C p.N27T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV101208184; called by muse, mutect2, varscan2
- CACNA1C | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538694667, COSV100223550; called by muse, mutect2, varscan2
- CALU | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.278); catalogued as COSV99975997; called by muse, varscan2
- CATSPERG | c.2022C>A p.H674Q | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99287070; called by muse, mutect2, varscan2
- CD226 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.091); catalogued as rs761166204, COSV99711639; called by muse, mutect2, varscan2
- CDH23 | c.9419T>A p.L3140Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs371829335; called by muse, mutect2, varscan2
- CEP120 | c.2887C>T p.H963Y | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1207534207, COSV100071567; called by muse, mutect2, varscan2
- CEP170 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100318111; called by muse, mutect2, varscan2
- CEP250 | c.5036A>T p.K1679M | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100699249; called by muse, mutect2, varscan2
- CGREF1 | c.569A>C p.E190A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs756354883, COSV99565516; called by muse, mutect2, varscan2
- CREBBP | c.6074C>A p.P2025H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.425); catalogued as rs1010580725, COSV99272989; called by muse, mutect2, varscan2
- CSNK1E | c.142del p.Q48Sfs*11 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs1569079288; called by mutect2, pindel, varscan2
- CTSF | c.1312T>C p.Y438H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100074558; called by mutect2, varscan2
- DDX17 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV99319026; called by muse, mutect2, varscan2
- DIDO1 | c.1799T>A p.L600H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV99827608; called by muse, mutect2, varscan2
- DOCK7 | c.1210C>A p.H404N | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.993); catalogued as COSV99225477; called by muse, mutect2, varscan2
- GLP2R | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99302636; called by muse, mutect2, varscan2
- GLRA4 | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV101009741; called by muse, mutect2, varscan2
- HELZ2 | c.7472A>T p.K2491M (on ENST00000467148 / NM_001037335.2; = p.K1922M on NM_033405.3) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100918857; called by muse, mutect2, varscan2
- HELZ2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs780287876, COSV64409721; called by muse, mutect2, varscan2
- HERC4 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV99517664; called by muse, mutect2, varscan2
- KATNA1 | c.790A>T p.T264S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168113; called by muse, mutect2, varscan2
- KL | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV101199258; called by muse, mutect2, varscan2
- LCOR | c.922G>C p.G308R | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100603987; called by muse, mutect2, varscan2
- MARVELD3 | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.989); catalogued as rs867298559, COSV51705690, COSV99194896; called by muse, mutect2, varscan2
- MYO18A | c.3142C>G p.L1048V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.983); catalogued as COSV100572862; called by muse, mutect2, varscan2
- OR51E2 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101211413; called by muse, mutect2, varscan2
- PAFAH1B1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs868052564, COSV68210430; called by muse, mutect2
- PCSK1 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs774029532, COSV100227332; called by muse, mutect2, varscan2
- PDLIM2 | c.296T>C p.V99A (on ENST00000397760; = p.V349A on NM_021630.6) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV99748055; called by muse, mutect2, varscan2
- PLOD1 | c.1859T>G p.I620S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99539285; called by muse, mutect2, varscan2
- PLXNA3 | c.4777C>T p.R1593C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs192776944, COSV100860318, COSV63753749; called by muse, mutect2, varscan2
- PPA1 | c.353A>G p.D118G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs752094515, COSV100949989; called by muse, mutect2, varscan2
- RBM8A | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV100355448; called by muse, mutect2, varscan2
- RNF213 | c.8909C>T p.S2970L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100301745; called by muse, mutect2, varscan2
- RORB | c.500A>G p.Y167C (on ENST00000396204 / NM_001365023.1; = p.Y156C on NM_006914.4) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100974710; called by muse, mutect2, varscan2
- RP1 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs1472013734, COSV99609282; called by muse, mutect2, varscan2
- RTL6 | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV100373901; called by muse, mutect2, varscan2
- SALL3 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs761727616, COSV101610090; called by muse, mutect2, varscan2
- SH2B2 | c.451A>C p.K151Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.886); catalogued as rs782522258, COSV100159672; called by muse, mutect2, varscan2
- SH2D3C | c.833A>G p.Y278C (on ENST00000314830 / NM_170600.3; = p.Y121C on NM_005489.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100137805; called by muse, mutect2, varscan2
- SLC30A10 | c.367G>C p.G123R | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100751623; called by muse, mutect2, varscan2
- SULT1C4 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99731919; called by muse, mutect2, varscan2
- TAF7L | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768889307, COSV61256179; called by muse, mutect2, varscan2
- TAS2R31 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs766412084, COSV101115953; called by muse, varscan2
- TIAM2 | c.4102C>A p.L1368M (on ENST00000529824; = p.L1339M on NM_012454.3) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as COSV51643639, COSV99266112; called by muse, mutect2, varscan2
- TMEM106B | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.163); catalogued as COSV101188892; called by muse, mutect2, varscan2
- TMPRSS11D | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as COSV99385131; called by muse, mutect2, varscan2
- TNKS2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs765942229, COSV100861184; called by muse, mutect2, varscan2
- TPH2 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100422479; called by muse, mutect2, varscan2
- TRIM8 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100193534; called by muse, mutect2, varscan2
- TUT1 | c.726C>A p.D242E | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99545700; called by muse, mutect2, varscan2
- ZCCHC2 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377112503; called by muse, mutect2, varscan2
- ZNF546 | c.2413T>C p.Y805H | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV100713600; called by muse, mutect2, varscan2
- ZNF648 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.011); catalogued as COSV100374512; called by muse, mutect2, varscan2
- ZNF823 | c.635G>T p.R212I (on ENST00000341191 / NM_001297610.2; = p.R168I on NM_017507.2) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs953454323, COSV100362686; called by muse, mutect2, varscan2
- ATG14 | c.1421_1424del p.I474Tfs*7 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- ATG7 | c.1981_1990del p.G661Sfs*2 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel*, varscan2
- BAP1 | c.540_541del p.F181* | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by pindel, varscan2
- C15orf39 | c.1103_1105del p.P368del | In Frame Del (DEL) | VAF 26/95 reads (27%) | called by mutect2, pindel, varscan2
- CPSF6 | c.1514del p.K505Rfs*50 | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | called by mutect2, pindel, varscan2
- DOCK2 | c.3628_3629delinsA p.F1210Tfs*12 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | called by pindel, varscan2*
- EIF2AK3 | c.288dup p.E97Rfs*25 | Frame Shift Ins (INS) | VAF 45/214 reads (21%) | called by mutect2, pindel, varscan2
- EME1 | c.343_349del p.S115Pfs*45 | Frame Shift Del (DEL) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- KLHL15 | c.1612del p.T538Lfs*7 | Frame Shift Del (DEL) | VAF 55/145 reads (38%) | called by mutect2, pindel, varscan2
- SEMA6A | c.1861del p.A621Qfs*13 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- VHL | c.507_516dup p.E173Sfs*4 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- VKORC1L1 | c.250_251del p.N84Pfs*131 | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | called by mutect2, varscan2
- ADCY6 | c.1263G>A p.L421= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100327041; called by muse, mutect2, varscan2
- B4GALT2 | c.438G>T p.A146= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV52542406, COSV52543084; called by muse, mutect2, varscan2
- CNTNAP5 | c.603C>G p.L201= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV101444391; called by muse, mutect2, varscan2
- EVI2B | c.1131G>T p.L377= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV100445716; called by muse, mutect2, varscan2
- GLB1L2 | c.840G>T p.T280= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as rs1382294071; called by muse, mutect2
- IPO4 | c.2535G>T p.A845= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV100269342; called by muse, mutect2, varscan2
- LAPTM4B | c.246G>A p.A82= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100806231; called by muse, mutect2, varscan2
- MFHAS1 | c.2754C>T p.A918= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV52286982, COSV99360064; called by muse, mutect2, varscan2
- POLN | c.1267C>T p.L423= | Silent (SNP) | VAF 55/223 reads (25%) | catalogued as COSV101242881; called by muse, mutect2, varscan2
- PPARGC1A | c.141T>C p.D47= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99338912; called by muse, mutect2, varscan2
- PRG4 | c.2139T>A p.A713= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV100798356; called by muse, mutect2, varscan2
- SMC2 | c.2004A>T p.R668= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV99659940; called by muse, mutect2, varscan2
- SMYD4 | c.1902C>G p.R634= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100563302; called by muse, mutect2, varscan2
- XPOT | c.2124T>A p.L708= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100225803; called by muse, mutect2, varscan2
- XRN1 | c.1179G>A p.Q393= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as COSV99379152; called by muse, mutect2, varscan2
- YWHAH | c.528C>T p.A176= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99963865; called by muse, mutect2, varscan2
